Surgical pathology report (de-identified scan), TCGA case TCGA-EK-A2H1, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-EK-A2H1-01A (Primary Tumor).

[page 1 of 5]
IMFSA Discrepancy		☒

6/14/11

AGE: 1

PATIENT: [REDACTED] ACCT #: [REDACTED] LOC: [REDACTED] U#: [REDACTED]
REG DR: [REDACTED] E/SX: /F RM/BED: [REDACTED] REG: [REDACTED]
TUS: [REDACTED] TLOC: [REDACTED] DIS: [REDACTED]

SPEC #: [REDACTED] Obtained: [REDACTED] Subm Dr: [REDACTED]
STATUS: [REDACTED] Received: [REDACTED]

CLINICAL HISTORY:
CERVICAL CANCER

SPECIMEN/PROCEDURE:

1. LYMPH NODE - LEFT EXTERNAL ILIAC
2. LYMPH NODE - RIGHT EXTERNAL ILIAC
3. LYMPH NODE - RIGHT OBTURATOR
4. LYMPH NODE - RIGHT PARA AORTIC
5. LYMPH NODE - RIGHT COMMON ILIAC
6. LYMPH NODE - RIGHT EXTERNAL ILIAC
7. LYMPH NODE - LEFT EXTERNAL ILIAC
8. LYMPH NODE - LEFT PARA AORTIC
9. LYMPH NODE - LEFT COMMON ILIAC
10. LYMPH NODE - LEFT OBTURATOR
11. CERVIX - BX FOR

ICD-0-3
carcinoma, squamous cell, non keratinizing, NOS
8072/3
Site: Cervix, NOS C53.9
pw 6/16/11

IMPRESSION:

- 1) LYMPH NODE, LEFT EXTERNAL ILIAC, DISSECTION:
. One lymph node, negative for metastasis (0/1).
- 2) LYMPH NODE, RIGHT EXTERNAL ILIAC, DISSECTION:
. Benign fibroadipose tissue, no lymph node identified.
- 3) LYMPH NODE, RIGHT OBTURATOR, DISSECTION:
. One lymph node, negative for metastasis (0/1).
- 4) LYMPH NODE, RIGHT PARAAORTIC, DISSECTION:
. Two lymph nodes, negative for metastasis (0/2).
- 5) LYMPH NODE, RIGHT COMMON ILIAC, DISSECTION:
. Two lymph nodes, negative for metastasis (0/2).
- 6) LYMPH NODE, RIGHT EXTERNAL ILIAC, DISSECTION:
. Five lymph nodes, negative for metastasis (0/5).
- 7) LYMPH NODE, LEFT EXTERNAL ILIAC, DISSECTION:
. Seven lymph nodes, negative for metastasis (0/7).
- 8) LYMPH NODE, LEFT PARAAORTIC, DISSECTION:

** CONTINUED ON NEXT PAGE **

[page 2 of 5]
IMPRESSION: (continued)

. Seven lymph nodes, negative for metastasis (0/7).

9) LYMPH NODE, LEFT COMMON ILIAC, DISSECTION:

. Four lymph nodes, negative for metastasis (0/4).

10) LYMPH NODE, LEFT OBTURATOR, DISSECTION:

. Five lymph nodes, negative for metastasis (0/5).

11) CERVICAL BIOPSY:

. Invasive squamous cell carcinoma, nonkeratizing, poorly differentiated.

Dictated

Entered:

COMMENT:

Case reviewed

Entered:

SPECIAL STAINS/PROCEDURES:

Two initial frozen sections, 1F, 2F.

Dictated by:

GROSS DESCRIPTION:

- 1) Received in formalin, labeled with the patient's name, number and "left external iliac", is a 1.8 x 1.0 x 0.8 cm, yellow tan, soft to firm lymph node. The specimen was entirely submitted for frozen section.

FROZEN SECTION DIAGNOSIS: One lymph node, negative for metastasis. This diagnosis was given

The frozen section specimen is being entirely submitted for permanent section in cassette labeled 1F.

- 2) Received in formalin, labeled with the patient's name, number and "right external iliac", is a 2.0 x 1.5 x 0.7 cm, yellow tan, soft to firm lymph node. The specimen was bisected and entirely submitted for frozen section.

FROZEN SECTION DIAGNOSIS: One lymph node, negative for metastasis. This diagnosis was given by

[page 3 of 5]
GROSS DESCRIPTION: (continued)

The frozen section specimen is being entirely submitted for permanent section in cassette labeled 2F. The remaining specimen is being entirely submitted in cassette 2A (fat).

- 3) Received in formalin, labeled "right obturator lymph node" and with the patient's name, is an irregular portion of yellow-tan lobulated adipose tissue, 3.5 x 3.0 x 1.3 cm. The specimen is dissected for lymph nodes, there is one pink-tan ovoid lymph node identified, 2.3 x 1.0 x 0.5 cm. All lymph nodes identified are submitted as follows:

CASSETTE SUMMARY:

Cassette 3: One lymph node, bivalved.

- 4) Received in formalin, labeled "right para-aortic lymph node" and with the patient's name, are two pink-tan to red-tan ovoid lymph nodes, 2.0 x 1.0 x 0.5 cm and 1.0 x 0.7 x 0.3 cm. All lymph nodes identified are submitted as follows:

CASSETTE SUMMARY:

Cassette 4A: One lymph node.

Cassette 4B: One lymph node, bivalved.

- 5) Received in formalin, labeled "right common iliac lymph node" and with the patient's name, is an irregular portion of yellow-tan lobulated adipose tissue, 4.5 x 1.0 x 0.7 cm. The specimen is dissected for lymph nodes, there are two pink-tan to red-tan ovoid lymph nodes identified, 1.0 x 0.5 x 0.3 cm and 2.5 x 1.1 x 0.7 cm. All lymph nodes identified are submitted as follows:

CASSETTE SUMMARY:

Cassette 5A: One lymph node.

Cassette 5B: One lymph node, bivalved.

- 6) Received in formalin, labeled "right external iliac lymph node" and with the patient's name, are two irregular unoriented portions of yellow-tan to pink-tan lobulated adipose tissue, ranging from 1.7 x 1.0 x 0.7 cm and 5.5 x 1.5 x 0.7 cm. The specimen is dissected for lymph nodes, there are five pink-tan ovoid lymph nodes identified, ranging from 0.6 x 0.4 x 0.2 cm to 2.0 x 1.2 x 0.8 cm. All lymph nodes identified are submitted as follows:

CASSETTE SUMMARY:

Cassette 6A: Three lymph nodes.

Cassette 6B: One lymph node.

Cassette 6C: One lymph node, bivalved.

- 7) Received in formalin, labeled "left external iliac lymph node" and with the patient's name, is an aggregate of irregular portions of yellow-tan lobulated adipose tissue, 3.5 x 3.0 x 1.5 cm. The specimen is dissected for lymph nodes, there are seven pink-tan ovoid lymph nodes identified, ranging from 0.8 x 0.7 x 0.4 cm to 3.5 x 1.0 x

** CONTINUED ON NEXT PAGE **

[page 4 of 5]
GROSS DESCRIPTION: (continued)

0.3 cm. All lymph nodes identified are submitted as follows:

CASSETTE SUMMARY:

Cassette 7A: One lymph node, bivalved.
Cassette 7B: One lymph node, bivalved.
Cassette 7C: One lymph node, bivalved.
Cassette 7D: One lymph node.
Cassette 7E: One lymph node.
Cassette 7G: One lymph node.
Cassette 7H: One lymph node, bisected.

- 8) Received in formalin, labeled "right para-aortic lymph nodes" and with the patient's name, is an irregular portion of yellow-tan lobulated adipose tissue, 4.5 x 2.2 x 0.7 cm. The specimen is dissected for lymph nodes, there are seven pink-tan to red-tan ovoid lymph nodes identified, ranging from 1.1 x 0.8 x 0.2 cm to 2.3 x 1.1 x 0.5 cm. All lymph nodes identified are submitted as follows:

CASSETTE SUMMARY:

Cassette 8A: Two lymph nodes.
Cassette 8B: Three lymph nodes.
Cassette 8C: One lymph node, bivalved.
Cassette 8D: One lymph node, bivalved.

- 9) Received in formalin, labeled "left common iliac lymph node" and with the patient's name, are two irregular portions of yellow-tan lobulated adipose tissue, 2.0 x 1.3 x 0.5 cm and 1.5 x 1.5 x 0.8 cm. The specimen is dissected for lymph nodes, there are three red-tan to pink-tan ovoid lymph nodes identified, ranging from 0.4 x 0.4 x 0.3 cm to 1.8 x 0.9 x 0.3 cm. All lymph nodes identified are submitted as follows:

CASSETTE SUMMARY:

Cassette 9A: Three lymph nodes.
Cassette 9B: One lymph node.

- 10) Received in formalin, labeled "left obturator lymph node" and with the patient's name, is an irregular portion of yellow-tan lobulated adipose tissue, 6.5 x 2.5 x 1.3 cm. The specimen is dissected for lymph nodes, there are five pink-tan ovoid lymph nodes identified, ranging from 0.7 x 0.7 x 0.4 cm to 2.5 x 1.0 x 0.3 cm. All lymph nodes identified are submitted as follows:

CASSETTE SUMMARY:

Cassette 10A: Two lymph nodes.
Cassette 10B: Two lymph nodes.
Cassette 10C: One lymph node, bivalved.

- 11) Received in formalin, labeled with the patient's name, are seven irregular unoriented portions of pink-tan to red-tan rubbery tissue, ranging from 0.3 x 0.2 x 0.1 cm to 1.5

** CONTINUED ON NEXT PAGE **

[page 5 of 5]
SPEC #:

PATIENT:

Page: 5
(Continued)

GROSS DESCRIPTION: (continued)

x 0.8 x 0.3 cm. The largest portion of tissue is serially sectioned at close intervals, the specimen is entirely submitted in one cassette.

Dictated by:

Entered:

COPIES TO:

CPT Codes:

FS INITIAL-88331/3998710/2, CERVICAL BIOPSY (1)/88305/3997100,
LYMPH NODE, REGIONAL RESECT/88307/3998030/10

ICD9 Codes:

180.9

Resident Physician:

I have personally reviewed the material
(specimen/slide) and approve this final report.

Electronically Signed by: _____

** END OF REPORT **

Source: NCI Genomic Data Commons file b4ef9da3-0e06-4b7b-9f50-8dd86968fcb0 (TCGA-EK-A2H1.90313D4A-1DB7-42E5-8778-2CB92794B05D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).